Somatic mutation profile of tumor specimen ALCH-B34K-TTP1-A (aliquot ALCH-B34K-TTP1-A-2-0-D-A77J-36) from ALCHEMIST case ALCH-B34K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.9 years (25,544 days).
Specimen ALCH-B34K-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2a05c2e-11fc-4878-b414-f694cca65bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34K-NB1-A (Blood Derived Normal), aliquot ALCH-B34K-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72f742ad-91f9-41c7-a11e-4a178fb61b75

The open-access MAF lists 93 somatic variants for this specimen: 53 protein-altering or splice-affecting, 30 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 30, Intron 4, Splice Region 2, 3'Flank 2, 3'UTR 1, In Frame Del 1, RNA 1, Splice Site 1, 5'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 27/521 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 82/517 reads (16%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ANKRD44 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV56552339; called by muse, mutect2
- CCDC150 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.439); catalogued as rs766996934; called by muse, mutect2
- DCC | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 58/616 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs1167613349; called by muse, mutect2
- DUXA | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as rs202088667, COSV73729638; called by muse, mutect2
- FAM178B | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs999993618; called by muse, mutect2
- FAM8A1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1181144404; called by muse, mutect2
- FAT4 | c.12680G>A p.R4227Q | Missense Mutation (SNP) | VAF 63/817 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs759859751, COSV58675438; called by muse, mutect2
- GSPT2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61214463, COSV61214583; called by muse, mutect2
- HES6 | c.354C>G p.D118E | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as rs1244163453; called by muse, mutect2
- HOXD1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs1226239450; called by muse, mutect2
- LRIT3 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV59985451; called by muse, mutect2
- MROH2B | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs202211129; called by muse, mutect2
- NDST3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 21/444 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs377531754, COSV56618069; called by muse, mutect2
- NT5DC3 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67323384; called by muse, mutect2
- OR10H5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs535367686; called by muse, mutect2
- PAPPA2 | c.3316C>A p.L1106M | Missense Mutation (SNP) | VAF 18/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62792673; called by muse, mutect2
- PCDHA5 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as rs1554128218; called by muse, mutect2
- PCDHGA6 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs968410543, COSV53962893; called by muse, mutect2
- PHKB | c.1900A>G p.I634V | Missense Mutation (SNP) | VAF 50/838 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs145723243; called by muse, mutect2
- PLEC | c.5431C>T p.R1811W (on ENST00000322810 / NM_201380.4; = p.R1701W on NM_000445.5) | Missense Mutation (SNP) | VAF 11/332 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs782306391; called by muse, mutect2
- RYR2 | c.12404G>A p.R4135H | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764202302, COSV63657848, COSV63684883; ClinVar: uncertain significance; called by muse, mutect2
- TGM5 | c.1123C>T p.P375S (on ENST00000220420 / NM_201631.4; = p.P293S on NM_004245.4) | Missense Mutation (SNP) | VAF 38/624 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55009937; called by muse, mutect2
- TMEM177 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV55608672; called by muse, mutect2
- TTC30A | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs773591734; called by muse, mutect2
- ABCB8 | c.2116C>T p.L706F (on ENST00000297504 / NM_001282291.2; = p.L689F on NM_007188.5) | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACKR1 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ANGPT4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCDC127 | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTTN | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- DNAJC5 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2
- DRAXIN | c.565T>C p.F189L | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DYNC1H1 | c.5042G>C p.G1681A | Missense Mutation (SNP) | VAF 15/474 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- EIF2AK3 | c.2159G>C p.R720T | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- GGCX | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 17/594 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- GRAP2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 37/371 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HFE | c.892+7G>A | Splice Region (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- HMCN1 | c.7003A>G p.K2335E | Missense Mutation (SNP) | VAF 26/853 reads (3%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.994); called by muse, mutect2
- IRF2BP1 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAST1 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 31/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MIB2 | c.1869-3C>G | Splice Region (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- MYO16 | c.2175A>G p.I725M | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- PJA2 | c.775T>G p.S259A | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- PRICKLE3 | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- RAPH1 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SEZ6L2 | c.968A>T p.Q323L (on ENST00000308713 / NM_001114099.3; = p.Q253L on NM_012410.4) | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- SNX2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- STAB2 | c.2647-1G>A p.X883_splice | Splice Site (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- TRBC2 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 22/495 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF526 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 70/652 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZSCAN26 | c.1001G>A p.G334E (on ENST00000623276 / NM_001111039.2; = p.G200E on NM_152736.5) | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZSCAN4 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF7 | c.87C>T p.G29= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- CCDC150 | c.1209C>T p.I403= | Silent (SNP) | VAF 60/584 reads (10%) | catalogued as rs760976525, COSV55878209; called by muse, varscan2
- CHST8 | c.699C>G p.L233= | Silent (SNP) | VAF 44/272 reads (16%) | catalogued as COSV52855927; called by muse, mutect2, varscan2
- CR1L | c.603T>C p.G201= | Silent (SNP) | VAF 44/944 reads (5%) | called by muse, mutect2
- CRHR1 | c.282C>T p.A94= | Silent (SNP) | VAF 59/376 reads (16%) | catalogued as rs1299308082; called by muse, mutect2, varscan2
- DCAF1 | c.4335C>T p.N1445= | Silent (SNP) | VAF 18/436 reads (4%) | catalogued as rs1553625537; called by muse, mutect2
- DCAF5 | c.729C>T p.S243= | Silent (SNP) | VAF 23/377 reads (6%) | called by muse, mutect2
- DRC1 | c.2040C>G p.L680= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- FAM107B | c.69G>T p.P23= | Silent (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- FAM214A | c.2013C>G p.G671= | Silent (SNP) | VAF 11/161 reads (7%) | catalogued as COSV99957958; called by muse, mutect2
- GPR26 | c.795C>A p.L265= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- GSPT2 | c.144C>T p.F48= | Silent (SNP) | VAF 16/296 reads (5%) | catalogued as COSV100468454; called by muse, mutect2
- HECW1 | c.2391G>A p.R797= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- KIF26B | c.39C>G p.V13= | Silent (SNP) | VAF 23/296 reads (8%) | called by muse, mutect2
- LHFPL5 | c.267C>A p.I89= | Silent (SNP) | VAF 37/752 reads (5%) | called by muse, mutect2
- MDFIC | c.414C>T p.S138= | Silent (SNP) | VAF 40/541 reads (7%) | called by muse, mutect2
- MRC1 | c.963T>G p.P321= | Silent (SNP) | VAF 39/885 reads (4%) | called by muse, mutect2
- N4BP2 | c.4833C>T p.F1611= | Silent (SNP) | VAF 12/263 reads (5%) | called by muse, mutect2
- NCKAP5 | c.2070T>C p.T690= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- NUP214 | c.6228G>A p.G2076= | Silent (SNP) | VAF 45/513 reads (9%) | called by muse, mutect2
- OR10J3 | c.807G>T p.L269= | Silent (SNP) | VAF 28/410 reads (7%) | called by muse, mutect2
- PLXNA4 | c.3336C>T p.T1112= | Silent (SNP) | VAF 48/609 reads (8%) | catalogued as rs181526936; called by muse, mutect2
- PRG4 | c.2571C>G p.V857= | Silent (SNP) | VAF 130/471 reads (28%) | catalogued as rs1359396742; called by muse, mutect2, varscan2
- SLC25A29 | c.63G>C p.P21= | Silent (SNP) | VAF 21/248 reads (8%) | called by muse, mutect2
- SMG1 | c.8988C>A p.I2996= | Silent (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- STT3B | c.1488G>A p.E496= | Silent (SNP) | VAF 17/331 reads (5%) | catalogued as rs1360281230; called by muse, mutect2
- SUGCT | c.1104C>T p.G368= (on ENST00000335693 / NM_001193313.2; = p.G394= on NM_024728.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/636 reads (5%) | called by muse, mutect2
- TNRC6A | c.756A>G p.E252= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- ZNF317 | c.1656C>T p.H552= | Silent (SNP) | VAF 14/366 reads (4%) | called by muse, mutect2
- ZNF449 | c.312G>C p.L104= | Silent (SNP) | VAF 15/589 reads (3%) | called by muse, mutect2
- ASCC2 | c.-106C>T | 5'UTR (SNP) | VAF 16/207 reads (8%) | catalogued as COSV100316582; called by muse, mutect2
- GGT1 | chr22:24633354 T>C | 3'Flank (SNP) | VAF 17/429 reads (4%) | called by muse, mutect2
- GPS1 | chr17:82051491 C>T | 5'Flank (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- ITK | c.*9G>T | 3'UTR (SNP) | VAF 62/712 reads (9%) | called by muse, mutect2
- MARVELD3 | chr16:71640536 G>A | 3'Flank (SNP) | VAF 19/511 reads (4%) | called by muse, mutect2
- NDUFS8 | c.109+30G>A | Intron (SNP) | VAF 33/352 reads (9%) | catalogued as rs1281704356; called by muse, mutect2
- NFKBIA | c.637-12T>C | Intron (SNP) | VAF 52/750 reads (7%) | called by muse, mutect2
- OBSCN | c.11659+4270C>T | Intron (SNP) | VAF 47/351 reads (13%) | called by muse, mutect2, varscan2
- SGCD | c.696+50del | Intron (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- SSPOP | n.11754C>T | RNA (SNP) | VAF 12/101 reads (12%) | catalogued as rs995384137; called by muse, mutect2, varscan2
